Somatic mutation profile of tumor specimen TCGA-28-1746-01A (aliquot TCGA-28-1746-01A-01W-0643-08) from TCGA case TCGA-28-1746, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: female; Vital status: Alive; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 77.5 years (28,302 days).
Specimen TCGA-28-1746-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bd7a0405-bd5e-4a7b-bd4c-1ad278eaa8cd.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-28-1746-10A (Blood Derived Normal), aliquot TCGA-28-1746-10A-01W-0643-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0bc5b7e8-ccfc-4d56-ab3b-12c25ed87754

The open-access MAF lists 75 somatic variants for this specimen: 48 protein-altering or splice-affecting, 26 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 42, Silent 26, Nonsense Mutation 3, Frame Shift Del 2, Intron 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTEN | c.212G>A p.C71Y | Missense Mutation (SNP) | VAF 30/45 reads (67%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64295132, COSV64296674, COSV64298389; called by muse, mutect2, varscan2
- TP53 | c.824G>A p.C275Y | Missense Mutation (SNP) | VAF 30/64 reads (47%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs863224451, CM076568, CM951234, COSV52661919, COSV52663595, COSV52675710, COSV52772708; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- AGAP3 | c.2482C>T p.R828W (on ENST00000622464; = p.R864W on NM_031946.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); catalogued as rs755984686, COSV99880745; called by muse, mutect2, varscan2
- C1QL2 | c.662C>T p.A221V | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT tolerated (0.36); PolyPhen benign (0.211); catalogued as rs778909990, COSV55607513; called by muse, mutect2
- C8B | c.1650C>G p.C550W | Missense Mutation (SNP) | VAF 23/73 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100980686, COSV64777946; called by muse, mutect2, varscan2
- CAPN3 | c.1157G>A p.R386H | Missense Mutation (SNP) | VAF 86/104 reads (83%) | SIFT deleterious (0.01); PolyPhen benign (0.052); catalogued as rs376273996; called by muse, mutect2, varscan2
- CATSPERB | c.1576C>T p.L526F | Missense Mutation (SNP) | VAF 37/103 reads (36%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as COSV99830829; called by muse, mutect2, varscan2
- CHGB | c.1612A>G p.R538G | Missense Mutation (SNP) | VAF 8/193 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.673); catalogued as COSV100972910; called by muse, mutect2
- CHRNA10 | c.206T>C p.M69T | Missense Mutation (SNP) | VAF 123/356 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV99167305; called by muse, mutect2, varscan2
- CLTRN | c.211C>T p.H71Y | Missense Mutation (SNP) | VAF 79/197 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.346); catalogued as rs1376197217, COSV100574825; called by muse, mutect2, varscan2
- DOK1 | c.958G>A p.D320N | Missense Mutation (SNP) | VAF 61/152 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.083); catalogued as COSV99283930; called by muse, mutect2, varscan2
- FAM83G | c.1072G>A p.D358N | Missense Mutation (SNP) | VAF 8/13 reads (62%) | SIFT tolerated (0.08); PolyPhen benign (0.158); catalogued as rs563466170, COSV100524818; called by muse, mutect2, varscan2
- FBLN5 | c.191G>A p.G64D | Missense Mutation (SNP) | VAF 50/111 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99969341; called by muse, mutect2, varscan2
- G6PD | c.1294A>C p.K432Q | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT tolerated (0.2); PolyPhen benign (0.093); catalogued as COSV100854933; called by muse, mutect2, varscan2
- GABRG2 | c.982G>A p.V328I (on ENST00000361925 / NM_001375343.1; = p.V288I on NM_000816.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 114/309 reads (37%) | SIFT tolerated (0.64); PolyPhen probably damaging (0.983); catalogued as rs768565280, COSV62719273; called by muse, mutect2, varscan2
- GRIP1 | c.1490T>A p.L497H (on ENST00000359742 / NM_001379345.1; = p.L445H on NM_021150.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 62/139 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as COSV99668079; called by muse, mutect2, varscan2
- HAUS7 | c.721G>A p.A241T | Missense Mutation (SNP) | VAF 29/70 reads (41%) | SIFT tolerated (0.37); PolyPhen benign (0.007); catalogued as rs1336487997, COSV57848342; called by muse, mutect2, varscan2
- HCAR3 | c.988G>A p.E330K | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (0.2); PolyPhen benign (0.055); catalogued as rs774684204, COSV100811461; called by muse, mutect2, varscan2
- INTS12 | c.1052A>G p.N351S | Missense Mutation (SNP) | VAF 197/407 reads (48%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0); catalogued as rs184986813, COSV100415675; called by muse, mutect2, varscan2
- ITIH5 | c.1016G>A p.R339Q | Missense Mutation (SNP) | VAF 12/134 reads (9%) | SIFT tolerated (0.1); PolyPhen benign (0.191); catalogued as rs753071487, COSV99903760; called by muse, mutect2
- ITSN2 | c.3494G>A p.W1165* | Nonsense Mutation (SNP) | VAF 103/211 reads (49%) | catalogued as COSV100742714; called by muse, mutect2, varscan2
- KIF2B | c.658A>G p.K220E | Missense Mutation (SNP) | VAF 27/67 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV99274712; called by muse, mutect2, varscan2
- MAGEA10 | c.489T>A p.S163R | Missense Mutation (SNP) | VAF 22/84 reads (26%) | SIFT tolerated (0.24); PolyPhen benign (0.024); catalogued as COSV99726576; called by muse, mutect2, varscan2
- MAGEH1 | c.133G>A p.E45K | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.011); catalogued as rs748430812, COSV61678893; called by muse, mutect2, varscan2
- MAN1A1 | c.1652C>A p.T551N | Missense Mutation (SNP) | VAF 99/292 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.699); catalogued as COSV100870582; called by muse, mutect2, varscan2
- MYO15A | c.7534G>A p.V2512M | Missense Mutation (SNP) | VAF 21/34 reads (62%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.95); catalogued as rs201619309; called by muse, mutect2, varscan2
- MYOCD | c.1184C>T p.T395M | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); catalogued as rs943300545, COSV100590195; called by mutect2, varscan2
- NAA25 | c.1540C>T p.R514* | Nonsense Mutation (SNP) | VAF 52/103 reads (50%) | catalogued as COSV55703099, COSV55705489; called by muse, mutect2, varscan2
- NSD1 | c.1310C>T p.S437L | Missense Mutation (SNP) | VAF 41/92 reads (45%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.026); catalogued as CM020744, COSV100728420, COSV100728435; called by muse, mutect2, varscan2
- OR51B6 | c.479G>A p.R160H | Missense Mutation (SNP) | VAF 88/245 reads (36%) | SIFT tolerated (0.59); PolyPhen benign (0.005); catalogued as rs112049705, COSV66512594; called by muse, mutect2
- OSCP1 | c.587G>A p.G196D (on ENST00000356637 / NM_001330493.1; = p.G186D on NM_145047.5) | Missense Mutation (SNP) | VAF 80/183 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99347022; called by muse, mutect2, varscan2
- OTOF | c.4891G>A p.G1631R (on ENST00000272371 / NM_194248.3; = p.G864R on NM_004802.4) | Missense Mutation (SNP) | VAF 10/16 reads (63%) | SIFT tolerated (0.68); PolyPhen possibly damaging (0.798); catalogued as COSV99716568; called by muse, varscan2
- PIAS3 | c.98G>A p.R33Q | Missense Mutation (SNP) | VAF 241/551 reads (44%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.536); catalogued as rs201917196; called by muse, mutect2, varscan2
- PLXNA2 | c.2731G>A p.A911T | Missense Mutation (SNP) | VAF 38/82 reads (46%) | SIFT tolerated (0.36); PolyPhen probably damaging (0.976); catalogued as rs750717398, COSV65438192; called by muse, mutect2, varscan2
- POLA1 | c.248-1G>A p.X83_splice | Splice Site (SNP) | VAF 218/472 reads (46%) | catalogued as COSV100985021; called by muse, mutect2, varscan2
- RPS10-NUDT3 | c.98C>T p.P33L | Missense Mutation (SNP) | VAF 37/110 reads (34%) | SIFT tolerated, low confidence (0.09); PolyPhen probably damaging (0.992); catalogued as rs754370248, COSV100402433; called by muse, mutect2, varscan2
- RPS6KA3 | c.1706G>T p.R569I | Missense Mutation (SNP) | VAF 44/98 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.784); catalogued as COSV101084143; called by muse, mutect2, varscan2
- SF3B2 | c.1117A>T p.T373S | Missense Mutation (SNP) | VAF 10/152 reads (7%) | SIFT tolerated (0.25); PolyPhen benign (0.366); catalogued as COSV100488263; called by muse, mutect2
- TDGF1 | c.50T>C p.M17T | Missense Mutation (SNP) | VAF 98/223 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.078); catalogued as rs767383421, COSV99947176; called by muse, mutect2, varscan2
- TMEM177 | c.146G>A p.W49* | Nonsense Mutation (SNP) | VAF 19/53 reads (36%) | catalogued as COSV99733528; called by muse, mutect2, varscan2
- TP53 | c.304del p.T102Pfs*21 | Frame Shift Del (DEL) | VAF 37/97 reads (38%) | catalogued as COSV53305997; called by mutect2, pindel, varscan2
- TRIM71 | c.2252G>A p.R751Q | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as COSV101070381; called by muse, mutect2, varscan2
- TTL | c.869T>A p.I290K | Missense Mutation (SNP) | VAF 50/120 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99271021; called by muse, varscan2
- USH2A | c.13641G>T p.E4547D | Missense Mutation (SNP) | VAF 58/244 reads (24%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.949); catalogued as COSV100229205, COSV56370849; called by muse, mutect2, varscan2
- XIRP2 | c.94C>G p.H32D | Missense Mutation (SNP) | VAF 53/133 reads (40%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.043); catalogued as COSV54687926, COSV99738662; called by muse, mutect2, varscan2
- ZNF157 | c.1324T>A p.Y442N | Missense Mutation (SNP) | VAF 110/190 reads (58%) | SIFT deleterious (0); PolyPhen possibly damaging (0.812); catalogued as COSV100998437; called by muse, mutect2, varscan2
- ANK3 | c.6765T>A p.H2255Q | Missense Mutation (SNP) | VAF 28/270 reads (10%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.021); called by mutect2, varscan2
- FAM13C | c.924del p.E308Dfs*20 | Frame Shift Del (DEL) | VAF 5/51 reads (10%) | called by mutect2, pindel
- ADH6 | c.822C>T p.D274= | Silent (SNP) | VAF 6/80 reads (8%) | catalogued as rs1249990904, COSV99421954; called by muse, mutect2
- AGFG1 | c.1233T>C p.V411= | Silent (SNP) | VAF 73/150 reads (49%) | catalogued as COSV100028383; called by muse, mutect2, varscan2
- B3GALNT2 | c.183C>T p.R61= | Silent (SNP) | VAF 105/258 reads (41%) | catalogued as COSV100010102; called by muse, mutect2, varscan2
- CAMP | c.315C>T p.D105= (on ENST00000296435; = p.D102= on NM_004345.5) | Silent (SNP) | VAF 13/20 reads (65%) | catalogued as rs201842351, COSV56482414; called by muse, mutect2, varscan2
- DNAH9 | c.11793C>T p.N3931= | Silent (SNP) | VAF 121/400 reads (30%) | catalogued as rs113001767; called by muse, mutect2, varscan2
- ENPP5 | c.1032G>A p.A344= | Silent (SNP) | VAF 6/21 reads (29%) | catalogued as rs375608028; called by muse, mutect2, varscan2
- ETV5 | c.123C>T p.H41= | Silent (SNP) | VAF 46/139 reads (33%) | catalogued as rs529743588, COSV100112054; called by muse, mutect2, varscan2
- FAM161A | c.1188T>C p.S396= | Silent (SNP) | VAF 26/90 reads (29%) | catalogued as COSV100281126; called by muse, mutect2, varscan2
- FUT6 | c.873C>T p.H291= | Silent (SNP) | VAF 12/68 reads (18%) | catalogued as rs571938720, COSV99744266; called by muse, varscan2
- GGCX | c.747G>A p.L249= | Silent (SNP) | VAF 36/84 reads (43%) | catalogued as COSV99289648; called by muse, varscan2
- GPHA2 | c.219G>A p.L73= | Silent (SNP) | VAF 16/30 reads (53%) | catalogued as rs762812588, COSV99375849; called by muse, mutect2
- KCNC2 | c.1737G>A p.T579= | Silent (SNP) | VAF 374/735 reads (51%) | catalogued as rs892456842, COSV100128241; called by muse, mutect2, varscan2
- L3MBTL1 | c.1308G>A p.Q436= (on ENST00000418998 / NM_001377303.1; = p.Q346= on NM_015478.7) | Silent (SNP) | VAF 63/179 reads (35%) | catalogued as COSV100916902; called by muse, mutect2, varscan2
- MS4A6E | c.186G>C p.L62= | Silent (SNP) | VAF 83/190 reads (44%) | catalogued as rs773294582, COSV100279085, COSV100279206; called by muse, mutect2, varscan2
- OR4M1 | c.654T>C p.Y218= | Silent (SNP) | VAF 333/1606 reads (21%) | catalogued as rs1337444477, COSV100270944, COSV100271569; called by muse, mutect2, varscan2
- OR7C1 | c.510C>T p.T170= | Silent (SNP) | VAF 125/266 reads (47%) | catalogued as COSV99934777; called by muse, mutect2, varscan2
- PCDHA4 | c.2118G>A p.A706= | Silent (SNP) | VAF 6/17 reads (35%) | catalogued as rs782718692, COSV63539392; called by muse, mutect2, varscan2
- POLE | c.6117G>A p.G2039= | Silent (SNP) | VAF 13/38 reads (34%) | catalogued as rs1317417382, COSV100265405; called by muse, mutect2, varscan2
- PRKCB | c.1890C>T p.F630= | Silent (SNP) | VAF 30/82 reads (37%) | catalogued as rs778710250, COSV57805894; called by muse, mutect2
- RRAD | c.783C>T p.N261= | Silent (SNP) | VAF 19/67 reads (28%) | catalogued as COSV100233598; called by muse, mutect2, varscan2
- SPINT2 | c.285C>T p.A95= | Silent (SNP) | VAF 6/25 reads (24%) | catalogued as COSV56649399; called by muse, mutect2
- STAT2 | c.1221G>A p.E407= | Silent (SNP) | VAF 110/245 reads (45%) | catalogued as COSV100028608; called by muse, mutect2, varscan2
- TIAM2 | c.1533G>A p.G511= | Silent (SNP) | VAF 16/39 reads (41%) | catalogued as rs761925506, COSV100018008; called by muse, mutect2
- TMCC2 | c.936C>T p.D312= | Silent (SNP) | VAF 12/36 reads (33%) | catalogued as COSV100319170; called by muse, mutect2, varscan2
- TTN | c.8937C>T p.N2979= (on ENST00000591111; = p.N2933= on NM_003319.4) | Silent (SNP) | VAF 43/91 reads (47%) | catalogued as rs368525666; ClinVar: likely benign; called by muse, mutect2, varscan2
- UBE3C | c.2613C>G p.L871= | Silent (SNP) | VAF 39/111 reads (35%) | catalogued as COSV100779772; called by muse, mutect2, varscan2
- EPB41L4B | c.1409+1941C>T | Intron (SNP) | VAF 193/540 reads (36%) | catalogued as COSV101000450; called by muse, mutect2, varscan2
